Somatic mutation profile of tumor specimen MP2PRT-PASYNP-TMP1-A (aliquot MP2PRT-PASYNP-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASYNP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.0 years (1,809 days).
Specimen MP2PRT-PASYNP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ba5b45e-6db5-4a5e-adeb-af0ea9c64811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYNP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYNP-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9bd2eea-15c4-4be8-b1ae-f93f1242eb9f

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Frame Shift Ins 3, Intron 1, Nonsense Mutation 1, 5'Flank 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB1 | c.2219C>T p.T740M (on ENST00000360697 / NM_001346687.2; = p.T700M on NM_001112.4) | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs377391425; called by muse, mutect2, varscan2
- AHNAK2 | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 62/630 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs772922301; called by muse, mutect2
- ALPK3 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 45/456 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs535488179; called by muse, mutect2
- MAGEB6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV66872891; called by muse, mutect2
- NAV3 | c.3272C>A p.A1091E | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99887077; called by muse, mutect2
- ZNF722P | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 48/499 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs112752244; called by muse, mutect2
- ALDOA | c.401_402insGGACC p.F134Lfs*32 (on ENST00000642816 / NM_001243177.4; = p.F80Lfs*32 on NM_184041.5) | Frame Shift Ins (INS) | VAF 51/619 reads (8%) | called by mutect2, pindel*
- CHRNA4 | c.656_658del p.N219del | In Frame Del (DEL) | VAF 134/570 reads (24%) | called by pindel, varscan2
- ERG | c.77_78insGT p.F26Lfs*16 | Frame Shift Ins (INS) | VAF 65/587 reads (11%) | called by mutect2, pindel, varscan2
- FREM1 | c.142A>T p.K48* | Nonsense Mutation (SNP) | VAF 114/475 reads (24%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1846T>A p.W616R | Missense Mutation (SNP) | VAF 52/1168 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- POLG | c.580dup p.A194Gfs*50 | Frame Shift Ins (INS) | VAF 85/814 reads (10%) | called by mutect2, pindel, varscan2
- ROBO3 | c.1270T>G p.C424G | Missense Mutation (SNP) | VAF 61/466 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPAP3 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIOBP | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 87/694 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- UBA2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 107/357 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- WNT11 | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 46/776 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2
- BMP5 | c.882T>G p.P294= | Silent (SNP) | VAF 46/495 reads (9%) | called by muse, mutect2
- BOD1L1 | c.78G>A p.P26= | Silent (SNP) | VAF 16/326 reads (5%) | catalogued as rs1223923940; called by muse, mutect2
- FAM160A1 | c.1665G>A p.P555= | Silent (SNP) | VAF 137/530 reads (26%) | catalogued as rs181059274; called by muse, mutect2, varscan2
- MN1 | c.3102G>A p.S1034= | Silent (SNP) | VAF 203/753 reads (27%) | catalogued as rs1252295774, COSV56557021; called by muse, mutect2, varscan2
- OR10S1 | c.507C>T p.H169= | Silent (SNP) | VAF 91/635 reads (14%) | catalogued as rs1187002987; called by muse, varscan2
- PEX5L | c.1179C>T p.N393= | Silent (SNP) | VAF 17/372 reads (5%) | called by muse, mutect2
- RAVER1 | c.1515C>T p.L505= (on ENST00000615032; = p.L661= on NM_133452.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/477 reads (6%) | called by muse, mutect2
- AGPAT4 | c.348+58dup | Intron (INS) | VAF 67/657 reads (10%) | called by mutect2, pindel, varscan2
- HDAC5 | chr17:44123543 C>T | 5'Flank (SNP) | VAF 130/958 reads (14%) | called by muse, varscan2
